Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A4U7, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A4U7-06A (Metastatic).

[page 1 of 2]
SPECIMEN(S):

- A. LEFT, EXTERNAL ILIAC LYMPH NODE
- B. LEFT COMMON ILIAC NODE
- C. LEFT OBTURATOR LYMPH NODES

CLINICAL HISTORY:

None Given

ICD-0-3
Melanoma, NOS 8720/3
Site: lymph node, iliac
C77.5

PRE-OPERATIVE DIAGNOSIS:

Left groin melanoma.

AW
10/10/12

DIAGNOSIS:

A. LYMPH NODE, LEFT EXTERNAL ILIAC, EXCISION:

- THREE OF THREE LYMPH NODES ARE POSITIVE FOR METASTATIC MELANOMA (3/3)

B. LYMPH NODE, LEFT COMMON ILIAC, EXCISION:

- ONE LYMPH NODE, POSITIVE FOR METASTATIC MELANOMA (1/1)

C. LYMPH NODE, LEFT OBTURATOR, EXCISION:

- TWO OF TWO LYMPH NODES, POSITIVE FOR METASTATIC MELANOMA (2/2)

GROSS DESCRIPTION:

A. LEFT, EXTERNAL LIAC LYMPH NODE

Received fresh labeled with the patient's identification and 'left external iliac lymph node' are three tan pink-black lymph nodes ranging from 5 x 2 x 1.4cm to 2 x 1.6 x 1.3cm. The specimens are serially sectioned. A portion of the specimen is submitted for tissue procurement. The remainder of the specimen is submitted as follows:

[page 2 of 2]
A1: one lymph node

A2-A4: one lymph node

A5-A7: one lymph node

B. LEFT COMMON ILIAC NODE

Received in formalin labeled with the patient's identification and 'left common iliac node' is a tan red-hemorrhagic lymph node 9 x 3 x 2cm. The specimen is serially sectioned. Entirely submitted in B1-B6.

C. LEFT OBTURATOR LYMPH NODES

Received fresh labeled with the patient's identification and 'left obturator lymph nodes' is a tan pink matter lymph node 5.5 x 4 x 3cm. The specimen is serially sectioned to reveal a hemorrhagic-necrotic cut surface. Representatively submitted in C1-C5.

ADDENDUM

Comment: Per clinician's request, the slides were re-reviewed.

The number of lymph nodes in specimen A and B remain the same.

The remaining tissue from specimen C was entirely submitted in cassettes C6 to C15. Three additional microscopic lymph nodes/lymphoid tissue were identified and one of them is positive for metastatic melanoma. Therefore the total number of lymph nodes in specimen C is 5.

DIAGNOSIS:

A. LYMPH NODE, LEFT EXTERNAL ILIAC, EXCISION:

- THREE OF THREE LYMPH NODES ARE POSITIVE FOR METASTATIC MELANOMA (3/3)

B. LYMPH NODE, LEFT COMMON ILIAC, EXCISION:

- ONE LYMPH NODE, POSITIVE FOR METASTATIC MELANOMA (1/1)

C. LYMPH NODE, LEFT OBTURATOR, EXCISION:

Source: NCI Genomic Data Commons file 781b7e0d-c80a-4d74-9df7-39a4ff15e235 (TCGA-GN-A4U7.D46EC94E-5D88-420B-97EB-D5754C299A29.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).